Somatic mutation profile of tumor specimen TARGET-50-PALFME-01A (aliquot TARGET-50-PALFME-01A-01D) from TARGET case TARGET-50-PALFME, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: male; Vital status: Dead; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 10.1 years (3,703 days).
Specimen TARGET-50-PALFME-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 801c5372-85df-41db-91ca-330723cf596e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PALFME-11A (Solid Tissue Normal), aliquot TARGET-50-PALFME-11A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c36b7103-d723-4ab5-b477-f18b4dda210d

The open-access MAF lists 12 somatic variants for this specimen: 11 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 9, Frame Shift Ins 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.1300dup p.L434Pfs*12 | Frame Shift Ins (INS) | VAF 7/32 reads (22%) | catalogued as rs398123715; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AOAH | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 65/95 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs148515077, COSV51747749; called by muse, mutect2, varscan2
- CHD4 | c.2621G>C p.R874P (on ENST00000357008 / NM_001363606.2; = p.R887P on NM_001273.5) | Missense Mutation (SNP) | VAF 98/317 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100539595, COSV58902522; called by muse, mutect2, varscan2
- LPCAT2 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 163/384 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs141449615; called by muse, mutect2, varscan2
- MAPK10 | c.845C>A p.A282E (on ENST00000359221 / NM_001351625.2; = p.A320E on NM_002753.5) | Missense Mutation (SNP) | VAF 28/517 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.025); catalogued as rs757125320, COSV60380345; called by muse, mutect2
- MFSD10 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as rs771938533, COSV53269862, COSV99296813; called by muse, mutect2, varscan2
- MMRN2 | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs778253708, COSV64400825; called by mutect2, varscan2
- STK11IP | c.808C>T p.R270W | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1337992060, COSV55250544; called by muse, mutect2, varscan2
- ZNF678 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59382491, COSV59383888; called by muse, mutect2, varscan2
- DSCAML1 | c.5474_5480dup p.T1828Lfs*14 (on ENST00000321322; = p.T1768Lfs*14 on NM_020693.4) | Frame Shift Ins (INS) | VAF 15/20 reads (75%) | called by mutect2, varscan2
- NPHP3 | c.301T>C p.F101L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); called by muse, mutect2
- MTUS2 | c.21T>C p.P7= | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2
